CCDI case PBBSTK — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/9b801c90-e5e8-411a-a494-7b68e8919ed6

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Neoplasm, malignant: ICD-O-3 morphology code: 8000/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 15.6 years (5,703 days).

Biospecimens (3 samples)
- Sample 0DHOIT: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DKWN9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DKWNM: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
